Somatic mutation profile of tumor specimen TCGA-GL-A9DE-01A (aliquot TCGA-GL-A9DE-01A-11D-A36X-10) from TCGA case TCGA-GL-A9DE, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 74.8 years (27,330 days).
Specimen TCGA-GL-A9DE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 015f0d98-9918-4d51-a1aa-cdd05108da91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GL-A9DE-10A (Blood Derived Normal), aliquot TCGA-GL-A9DE-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de1b667c-b0e5-409f-ba43-dee675507e6c

The open-access MAF lists 114 somatic variants for this specimen: 83 protein-altering or splice-affecting, 31 silent.
By variant classification: Missense Mutation 64, Silent 31, Frame Shift Del 8, Frame Shift Ins 5, Nonsense Mutation 3, In Frame Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER2 | c.1307T>A p.L436Q | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100766390; called by muse, mutect2, varscan2
- ANXA10 | c.536T>C p.V179A | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.253); catalogued as COSV100829133; called by muse, mutect2, varscan2
- ASB18 | c.1246G>C p.A416P | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100430841, COSV58233222; called by muse, mutect2
- ATP6V1H | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100778832, COSV62218223; called by muse, mutect2, varscan2
- ATP6V1H | c.1402G>C p.G468R | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100778834; called by muse, mutect2, varscan2
- BAZ1B | c.2789A>G p.H930R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs1554571705, COSV100290160; called by muse, mutect2, varscan2
- C2CD3 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100487456, COSV104396451; called by muse, mutect2, varscan2
- CACHD1 | c.1039G>T p.G347C | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99263335; called by muse, mutect2, varscan2
- CELF6 | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.021); catalogued as COSV99764191; called by muse, mutect2, varscan2
- CHTF18 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99135994; called by muse, mutect2, varscan2
- CLEC4C | c.368C>G p.T123S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.814); catalogued as COSV100665587; called by muse, mutect2, varscan2
- CNGB1 | c.1640C>T p.T547I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); catalogued as COSV99211652; called by muse, mutect2, varscan2
- CPSF3 | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99432185; called by muse, mutect2, varscan2
- CTSK | c.314C>G p.T105S | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0.225); catalogued as COSV99648990; called by muse, mutect2, varscan2
- CUEDC2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV56523043, COSV99827986; called by muse, mutect2, varscan2
- DHRS9 | c.409A>C p.N137H | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100513698; called by muse, mutect2, varscan2
- DIP2C | c.4376T>G p.I1459S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99793821; called by muse, mutect2, varscan2
- DMXL2 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.171); catalogued as COSV99198628; called by muse, mutect2, varscan2
- DNAJB8 | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 68/82 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs747091190, COSV100048503; called by muse, mutect2, varscan2
- FRY | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100969940; called by muse, mutect2, varscan2
- FUT4 | c.674A>T p.D225V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100708187; called by muse, mutect2, varscan2
- GPNMB | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV99326852; called by muse, mutect2, varscan2
- GPR34 | c.961T>A p.C321S | Missense Mutation (SNP) | VAF 97/128 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100587803; called by muse, mutect2, varscan2
- HERC2 | c.6360G>C p.E2120D | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99876797; called by muse, mutect2, varscan2
- HK3 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs1270326277, COSV99459423; called by muse, mutect2, varscan2
- HOOK2 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV99317846; called by muse, mutect2, varscan2
- HPS5 | c.137G>T p.W46L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100834482; called by muse, mutect2, varscan2
- IGSF3 | c.3190C>T p.R1064W (on ENST00000369486 / NM_001007237.3; = p.R1084W on NM_001542.4) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs777126397, COSV100605099; called by muse, mutect2, varscan2
- KIAA0408 | c.1761T>G p.N587K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV100847078, COSV64107682; called by muse, mutect2, varscan2
- KIAA1109 | c.9558A>C p.E3186D | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.754); catalogued as COSV99176554; called by muse, mutect2, varscan2
- KIF18B | c.2387G>A p.R796H (on ENST00000593135 / NM_001265577.2; = p.R808H on NM_001264573.2) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as rs778968636, COSV59274741; called by muse, mutect2, varscan2
- KMT2A | c.11341C>G p.L3781V | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100629913; called by muse, mutect2, varscan2
- LTBP1 | c.3299C>A p.S1100Y (on ENST00000404816 / NM_206943.4; = p.S774Y on NM_000627.4) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55384354, COSV99698867; called by muse, mutect2, varscan2
- LYST | c.2587G>A p.A863T | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV101090330; called by muse, mutect2, varscan2
- MCC | c.1580C>G p.A527G | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs147869500, COSV100203215; called by muse, mutect2, varscan2
- MRPL44 | c.527A>G p.E176G | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV99285335; called by muse, mutect2, varscan2
- MUC16 | c.38875C>A p.P12959T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.687); catalogued as COSV101201773; called by muse, mutect2, varscan2
- MYBPC1 | c.1221G>C p.K407N (on ENST00000550270 / NM_206820.2; = p.K432N on NM_002465.4) | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.88); catalogued as COSV100638291; called by muse, mutect2, varscan2
- NF1 | c.93T>G p.H31Q | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.039); catalogued as COSV100648313; called by muse, mutect2, varscan2
- PARD6B | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV100860040; called by muse, mutect2, varscan2
- PCLO | c.13060G>T p.V4354L | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV61682413; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100544538; called by muse, mutect2, varscan2
- POLR3GL | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.74); catalogued as COSV100996897; called by muse, mutect2, varscan2
- PTPN13 | c.2780T>C p.V927A | Missense Mutation (SNP) | VAF 122/284 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100365477; called by muse, mutect2, varscan2
- RAB6A | c.53T>A p.F18Y | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV100155348; called by muse, mutect2, varscan2
- RASSF3 | c.112-2A>C p.X38_splice | Splice Site (SNP) | VAF 27/59 reads (46%) | catalogued as COSV99309631; called by muse, varscan2
- RIOK1 | c.366A>G p.L122= | Splice Region (SNP) | VAF 86/227 reads (38%) | catalogued as COSV99344922; called by muse, mutect2, varscan2
- RNF14 | c.251C>A p.P84Q | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100641304; called by muse, mutect2, varscan2
- RPL35 | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as rs756084158, COSV100780876; called by muse, mutect2, varscan2
- RPTN | c.1496A>T p.Y499F | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV100285797; called by muse, mutect2, varscan2
- RRM1 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 95/210 reads (45%) | catalogued as COSV100331463; called by muse, mutect2, varscan2
- RTN1 | c.1814T>C p.F605S | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99956895; called by muse, mutect2, varscan2
- RUNDC3B | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV56692647, COSV56697482; called by muse, mutect2, varscan2
- SLC3A2 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV100101525; called by muse, mutect2, varscan2
- SLC3A2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV100101526; called by muse, mutect2, varscan2
- SLC7A4 | c.464C>G p.T155S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100298887; called by muse, mutect2, varscan2
- SNCAIP | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 34/78 reads (44%) | catalogued as COSV99750454; called by muse, mutect2, varscan2
- SNX16 | c.308G>C p.W103S | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100629705; called by muse, mutect2
- SPATA6 | c.633T>G p.I211M | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100893423; called by muse, mutect2, varscan2
- TCHH | c.4673G>A p.R1558H | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as rs756033778, COSV100915134, COSV100915493; called by muse, mutect2, varscan2
- TMEM176A | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.386); catalogued as COSV99134022; called by muse, mutect2, varscan2
- TRIM28 | c.412A>G p.S138G | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as COSV99449455; called by muse, mutect2, varscan2
- UBE2U | c.579A>T p.E193D | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as rs1356055767, COSV100934528; called by muse, mutect2, varscan2
- WAC | c.1789C>G p.H597D | Missense Mutation (SNP) | VAF 100/227 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.112); catalogued as COSV100611199; called by muse, mutect2, varscan2
- ZBED1 | c.1729T>G p.S577A | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV100586085; called by muse, mutect2, varscan2
- ZNF574 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.099); catalogued as rs1232606983, COSV99726538; called by muse, mutect2, varscan2
- ZNF695 | c.1404A>T p.E468D | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs955289941, COSV100377756; called by muse, mutect2, varscan2
- ZNF695 | c.1403A>T p.E468V | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100377758; called by muse, mutect2, varscan2
- BICRA | c.2319del p.S774Lfs*68 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- BSG | c.985del p.L329Wfs*37 | Frame Shift Del (DEL) | VAF 28/83 reads (34%) | called by mutect2, pindel, varscan2
- FMNL3 | c.1174_1175dup p.N392Kfs*3 | Frame Shift Ins (INS) | VAF 27/83 reads (33%) | called by mutect2, pindel, varscan2
- IPP | c.504_505dup p.V169Gfs*16 | Frame Shift Ins (INS) | VAF 48/136 reads (35%) | called by mutect2, pindel, varscan2
- KIF4B | c.1912del p.Q638Kfs*5 | Frame Shift Del (DEL) | VAF 158/438 reads (36%) | called by mutect2, pindel, varscan2
- LRIG1 | c.2782del p.R928Gfs*77 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.807dup p.L270Sfs*4 | Frame Shift Ins (INS) | VAF 30/44 reads (68%) | called by mutect2, pindel, varscan2
- NPC2 | c.165_166del p.Y55* | Nonsense Mutation (DEL) | VAF 25/64 reads (39%) | called by mutect2, pindel, varscan2
- PBRM1 | c.835dup p.I279Nfs*8 | Frame Shift Ins (INS) | VAF 29/37 reads (78%) | called by mutect2, varscan2
- PEX12 | c.675_679delinsTGGG p.R226Gfs*7 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by pindel, varscan2*
- PRPF40A | c.476_478del p.Q159del | In Frame Del (DEL) | VAF 48/444 reads (11%) | called by mutect2, pindel
- SCFD1 | c.1067_1068dup p.R357Nfs*9 | Frame Shift Ins (INS) | VAF 97/290 reads (33%) | called by mutect2, pindel, varscan2
- SETD2 | c.7546_7547delinsA p.V2516Ifs*2 | Frame Shift Del (DEL) | VAF 54/114 reads (47%) | called by pindel, varscan2*
- ZNF490 | c.1065_1066del p.T357Rfs*8 | Frame Shift Del (DEL) | VAF 36/92 reads (39%) | called by mutect2, pindel, varscan2
- ZNF596 | c.882del p.R295Efs*8 | Frame Shift Del (DEL) | VAF 51/145 reads (35%) | called by mutect2, pindel, varscan2
- ANPEP | c.6C>T p.A2= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100263551; called by muse, mutect2, varscan2
- C10orf67 | c.298T>C p.L100= (on ENST00000323327; = p.L101= on NM_153714.3) | Silent (SNP) | VAF 59/129 reads (46%) | catalogued as COSV100033727, COSV60113454; called by muse, mutect2, varscan2
- C16orf72 | c.630A>G p.P210= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as COSV100589134; called by muse, mutect2, varscan2
- CCNI | c.765T>C p.P255= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV99423662; called by muse, mutect2, varscan2
- COL17A1 | c.4047A>T p.A1349= | Silent (SNP) | VAF 96/252 reads (38%) | catalogued as COSV100212129; called by muse, mutect2, varscan2
- COL3A1 | c.1887A>G p.K629= | Silent (SNP) | VAF 113/294 reads (38%) | catalogued as COSV100483760; called by muse, varscan2
- DOT1L | c.1335G>T p.A445= | Silent (SNP) | VAF 48/109 reads (44%) | catalogued as COSV101288829, COSV67109176; called by muse, mutect2, varscan2
- DUXA | c.582T>C p.S194= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV101617160; called by muse, mutect2, varscan2
- EFCAB14 | c.1344G>A p.Q448= | Silent (SNP) | VAF 52/117 reads (44%) | catalogued as COSV100905669; called by muse, mutect2, varscan2
- EVC | c.2794A>C p.R932= | Silent (SNP) | VAF 92/219 reads (42%) | catalogued as COSV99382604; called by muse, mutect2, varscan2
- FASN | c.2058C>T p.F686= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as COSV100147632, COSV100148339; called by muse, mutect2, varscan2
- FOXQ1 | c.429G>T p.A143= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs755346081, COSV99723355; called by muse, mutect2, varscan2
- GUCY2D | c.807C>T p.T269= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as rs773415492, COSV99644287; called by muse, mutect2, varscan2
- INTS8 | c.291C>T p.D97= | Silent (SNP) | VAF 43/155 reads (28%) | catalogued as COSV100569488; called by muse, mutect2, varscan2
- KAZN | c.1614G>A p.L538= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV101057268; called by muse, mutect2, varscan2
- KRTAP17-1 | c.156C>T p.C52= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV100498599; called by muse, mutect2, varscan2
- LAMC3 | c.441C>A p.I147= | Silent (SNP) | VAF 49/130 reads (38%) | catalogued as COSV100736094; called by muse, mutect2, varscan2
- MYO9B | c.1335G>A p.K445= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV101261960; called by muse, mutect2, varscan2
- NUMA1 | c.4971T>C p.H1657= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV100672451; called by muse, mutect2, varscan2
- PLXNB2 | c.2502C>T p.D834= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV100834326; called by muse, mutect2, varscan2
- PPP4R1 | c.1098T>A p.T366= (on ENST00000400556 / NM_001042388.3; = p.T349= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as COSV99553997; called by muse, mutect2, varscan2
- PTPRH | c.204T>G p.T68= | Silent (SNP) | VAF 63/171 reads (37%) | catalogued as COSV99671473; called by muse, mutect2, varscan2
- RAB21 | c.510G>A p.E170= | Silent (SNP) | VAF 85/192 reads (44%) | catalogued as COSV99714993; called by muse, mutect2, varscan2
- RALBP1 | c.1953G>A p.K651= | Silent (SNP) | VAF 62/162 reads (38%) | catalogued as COSV99192040; called by muse, mutect2, varscan2
- SERPINA4 | c.351C>A p.V117= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100097490; called by muse, mutect2, varscan2
- SPEN | c.8769C>T p.V2923= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as rs1193736165, COSV101005628; called by muse, mutect2, varscan2
- SRSF4 | c.1206C>G p.S402= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV100861446; called by muse, varscan2
- TAF4 | c.1518A>T p.V506= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99435091; called by muse, mutect2, varscan2
- TMCC1 | c.660T>A p.S220= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV100261329; called by muse, mutect2
- ZFP36L1 | c.435C>A p.R145= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV100322933; called by muse, mutect2, varscan2
- ZNF251 | c.1266A>G p.E422= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV99478864; called by muse, mutect2, varscan2
